Somatic mutation profile of tumor specimen 0DDPQ8 from CCDI case PBBNWS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 14.3 years (5,224 days).
Specimen 0DDPQ8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfcfe93e-4e88-40ec-9ba3-c303b50f4015.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDPQ9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab932fc3-94ec-48d1-b305-c1b37d6b6117

The open-access MAF lists 15 somatic variants for this specimen: 7 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 7, Missense Mutation 7, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC22 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 200/267 reads (75%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs782549631; called by muse, mutect2, varscan2
- SLC4A5 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 32/513 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs369268833; called by muse, mutect2
- CENPO | c.781T>C p.S261P | Missense Mutation (SNP) | VAF 106/338 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FBXO33 | c.1292T>G p.V431G | Missense Mutation (SNP) | VAF 116/349 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- KMT2B | c.3077C>A p.T1026K | Missense Mutation (SNP) | VAF 165/412 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ST8SIA6 | c.467T>C p.V156A | Missense Mutation (SNP) | VAF 98/586 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ZBTB18 | c.1262G>C p.C421S | Missense Mutation (SNP) | VAF 147/369 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KIF21B | c.1911C>T p.A637= | Silent (SNP) | VAF 135/451 reads (30%) | catalogued as rs765071917, COSV100143360; called by muse, mutect2, varscan2
- LITAF | c.240C>T p.Y80= | Silent (SNP) | VAF 50/685 reads (7%) | catalogued as rs149184234; ClinVar: likely benign; called by muse, mutect2
- REPIN1 | c.1134C>T p.D378= | Silent (SNP) | VAF 171/440 reads (39%) | called by muse, mutect2, varscan2
- SCN7A | c.4401G>C p.G1467= | Silent (SNP) | VAF 85/399 reads (21%) | called by muse, mutect2, varscan2
- SKP2 | c.751T>C p.L251= | Silent (SNP) | VAF 212/616 reads (34%) | called by muse, mutect2, varscan2
- TMEM130 | c.696C>T p.F232= | Silent (SNP) | VAF 248/533 reads (47%) | catalogued as rs1554398938; called by muse, mutect2, varscan2
- TNRC6A | c.5151G>A p.L1717= | Silent (SNP) | VAF 34/540 reads (6%) | called by muse, mutect2
- GRIP1 | c.*38A>G | 3'UTR (SNP) | VAF 48/133 reads (36%) | called by muse, varscan2
